Somatic mutation profile of tumor specimen 0DTFRR from CCDI case PBCJUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Superior wall of nasopharynx; Age at diagnosis: 2.6 years (942 days).
Specimen 0DTFRR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b81149-bc30-4862-8e2e-11d2621b2184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFS0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b493b43-9b08-43fc-abb5-d82339e9e6d7

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 6, Silent 1, Splice Region 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 517/688 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD27 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 147/800 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs185770739, COSV60130554; called by muse, mutect2, varscan2
- APLNR | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 82/970 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373170562, COSV57241687; called by muse, mutect2
- IL11 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 108/667 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); catalogued as rs553947830, COSV52772509; called by muse, varscan2
- NUMA1 | c.2629C>T p.L877F | Missense Mutation (SNP) | VAF 116/933 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017677356; called by muse, mutect2, varscan2
- TECTA | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 111/461 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176214445, COSV50688438, COSV99881005; called by muse, mutect2, varscan2
- ZNF213 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1296230751; called by muse, varscan2
- ZNHIT2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 102/631 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs201399826; called by muse, mutect2, varscan2
- AC245033.1 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 151/828 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ATP10A | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 90/552 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CAPN11 | c.1226G>T p.R409M | Missense Mutation (SNP) | VAF 228/1894 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLNC | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 101/709 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HFE | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 170/1615 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/1705 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KMT2A | c.7887dup p.G2630Wfs*13 | Frame Shift Ins (INS) | VAF 80/185 reads (43%) | called by mutect2, varscan2
- MAD2L1BP | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 41/1619 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2
- PCDHA1 | c.749A>C p.H250P | Missense Mutation (SNP) | VAF 129/1117 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPGRIP1 | c.2559C>A p.F853L | Missense Mutation (SNP) | VAF 197/1184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TIGD3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 75/470 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- VPS50 | c.1262+7T>C | Splice Region (SNP) | VAF 95/653 reads (15%) | called by muse, mutect2, varscan2
- NR2F1 | c.558C>T p.S186= | Silent (SNP) | VAF 98/586 reads (17%) | catalogued as rs773102110; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1415G>A | Intron (SNP) | VAF 239/904 reads (26%) | catalogued as rs772628135, COSV63752260; called by muse, mutect2, varscan2
- EIF3I | c.803+84G>A | Intron (SNP) | VAF 46/106 reads (43%) | catalogued as rs1045237789; called by muse, mutect2, varscan2
- FAR2 | c.365+34C>T | Intron (SNP) | VAF 64/371 reads (17%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+2517A>T | Intron (SNP) | VAF 127/822 reads (15%) | called by muse, mutect2, varscan2
- LOXL1 | c.1506+68C>T | Intron (SNP) | VAF 77/428 reads (18%) | called by muse, mutect2, varscan2
- MARK4 | c.1494+93C>T | Intron (SNP) | VAF 22/111 reads (20%) | catalogued as rs1369779050; called by muse, mutect2, varscan2
- MRPS23 | c.-9G>A | 5'UTR (SNP) | VAF 85/625 reads (14%) | catalogued as rs751674773; called by muse, mutect2, varscan2
